Surgical pathology report (de-identified scan), TCGA case TCGA-VQ-AA6K, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VQ-AA6K-01A (Primary Tumor).

41E ICD-O-3
Adenocarcinoma, signet ring cell 8490/3
path
Adenocarcinoma, mucinous & signet ring cell 8480/3
8490/3 Code to highest 8490/3
Site: Cardia NOS C16.0

Collect date:

PATHOLOGY REPORT:

PRIMARY SITE: Stomach (Cardia)

1 - "Product of the esophagogastrrectomy according to the standardization":

- Poorly differentiated adenocarcinoma, intestinal type, with extensive areas of mucinous differentiation and signet ring cells, ulcerative and infiltrative, measuring 10.5 x 6.8cm, located in cardia region / body, infiltrating the wall up to the perigastric adipose tissue;
- Presence of perineural invasion;
- Presence of angiolymphatic invasion;
- Esophageal margin: free of tumor;
- Margin marked with surgical thread: free of tumor;
- Margin of gastric resection: compromised by neoplasm;
- Lymph node from chain 1: metastasis in 1 lymph node dissected (1/1);
- Lymph node from chain 2: metastasis in 1 lymph node dissected (1/1), with capsular transposition;
- Lymph node from chain 3: metastasis in 6 of 8 dissected lymph nodes (6/8) with capsular transposition and conglomerates of lymph nodes;
- Lymph node from chain 5: fragments of smooth muscle tissue free of cancer (0/0);
- Lymph node from chain 9: adipose tissue free of neoplasm (0/0);
- Lymph node from chain 10: metastasis in 1 lymph node out of 5 dissected (1/5)
- Accessory spleen free of neoplasia;
- Lymph node from chain 11p: metastasis in 1 dissected lymph node out of 5 (1/5)
- Fragment of pancreatic parenchyma free of neoplasia;
- Lymph node from chain 110: free of tumor (0/1).

2 - "Greater omentum"

- Fragment of mature adipose tissue free of neoplasm.

3 - "Esophagus":

- Esophageal segment free of neoplasia.

4 - "Esophageal margin":

- Free of neoplasia.

5 - "Spleen":

- Splenic parenchyma congested, free of neoplasia.

Source: NCI Genomic Data Commons file 4230e1af-c6e3-4fdf-a6f4-c771e39623bf (TCGA-VQ-AA6K.0F639715-8D41-4E63-B582-F24A42F23EBD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).